Somatic mutation profile of tumor specimen BA2044D (aliquot aq-BA2044D) from BEATAML1.0 case 2267, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,893 days).
Specimen BA2044D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73cb2a39-2650-4713-be71-5065a0f43f89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2968D (Solid Tissue Normal), aliquot aq-BA2968D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa45b01-7ec4-41fe-adf6-396cc547dc78

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Splice Region 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COX15 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 178/399 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1278838654; called by muse, mutect2, varscan2
- OR5M8 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs187777069; called by muse, mutect2, varscan2
- PTBP1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs780418434, COSV62459038; called by muse, varscan2
- RPAP1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV58542421; called by muse, mutect2, varscan2
- SEMA5B | c.2246G>T p.C749F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1307328940, COSV52098785; called by muse, mutect2
- TIE1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs776717207; called by muse, varscan2
- ZNF846 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs182054421, COSV67412740; called by muse, mutect2, varscan2
- CHD2 | c.2429T>C p.V810A | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MBD5 | c.2520C>G p.G840= | Splice Region (SNP) | VAF 26/52 reads (50%) | called by muse, varscan2
- RPAP1 | c.789A>T p.R263S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- RUNX1 | c.1050_1059delinsACTGCGCATT p.Y350_Y353delins* (on ENST00000344691 / NM_001001890.3; = p.Y377_Y380delins* on NM_001754.5) | Nonsense Mutation (ONP) | VAF 9/41 reads (22%) | called by pindel, varscan2*
- STK3 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2
- TMEM178B | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.1); called by muse, mutect2
- VSIG1 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 96/105 reads (91%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR45 | c.563T>G p.I188S (on ENST00000376372 / NM_001029896.2; = p.I189S on NM_007075.3) | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLK4 | c.432G>T p.A144= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV60675767; called by muse, mutect2
- OR5D18 | c.426C>T p.C142= | Silent (SNP) | VAF 51/105 reads (49%) | catalogued as rs748193440, COSV61737568; called by muse, mutect2, varscan2
- CNOT1 | c.4434+39T>C | Intron (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
